Somatic mutation profile of tumor specimen TCGA-A2-A0EY-01A (aliquot TCGA-A2-A0EY-01A-11W-A050-09) from TCGA case TCGA-A2-A0EY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.6 years (22,872 days).
Specimen TCGA-A2-A0EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 840b5680-118d-4100-abff-c0f3d3d34c2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0EY-10A (Blood Derived Normal), aliquot TCGA-A2-A0EY-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bc3f9ba-7c33-4f41-8df8-e32e6c478965

The open-access MAF lists 225 somatic variants for this specimen: 155 protein-altering or splice-affecting, 63 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 63, Nonsense Mutation 14, Splice Site 4, 5'Flank 3, Frame Shift Del 2, Intron 2, Splice Region 2, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.994); catalogued as rs121918011, CM127629, CM138789, CM980062; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 37/213 reads (17%) | catalogued as rs281874661, CM983305, COSV60355944; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 37/93 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 51/126 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP5 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54535252; called by muse, mutect2, varscan2
- ACSS3 | c.1355-1G>C p.X452_splice | Splice Site (SNP) | VAF 12/67 reads (18%) | catalogued as COSV54084749; called by muse, mutect2, varscan2
- ACSS3 | c.1871G>A p.R624K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54084758; called by muse, mutect2, varscan2
- ACTB | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.065); catalogued as COSV59316650; called by muse, mutect2, varscan2
- ACTR6 | c.570C>G p.Y190* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | catalogued as COSV51841053; called by muse, mutect2, varscan2
- AFF2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 478/1289 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53976131; called by muse, mutect2, varscan2
- AKAP12 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); catalogued as rs1401281476, COSV53570096; called by muse, mutect2, varscan2
- ANKRD12 | c.3572G>A p.R1191K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV50819116; called by muse, mutect2, varscan2
- APLN | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.127); catalogued as COSV100278301; called by muse, mutect2
- ASH2L | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV51698421; called by muse, mutect2, varscan2
- ATM | c.4759C>A p.P1587T | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs786202473, COSV53725599; called by muse, mutect2
- BAIAP2L2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60201305; called by muse, mutect2, varscan2
- BBS5 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV54751847; called by muse, mutect2, varscan2
- C5 | c.4015G>C p.E1339Q | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.946); catalogued as COSV56323737, COSV56323948; called by muse, mutect2, varscan2
- C9orf131 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56609565; called by muse, mutect2, varscan2
- CACNA1G | c.4932G>T p.K1644N | Missense Mutation (SNP) | VAF 99/150 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61720130; called by muse, mutect2, varscan2
- CACNA1G | c.5304G>C p.L1768= | Splice Region (SNP) | VAF 79/131 reads (60%) | catalogued as COSV61720142; called by muse, mutect2, varscan2
- CALD1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1028927629, COSV62645095; called by muse, mutect2, varscan2
- CALD1 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 106/352 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs1179534376, COSV62645101; called by muse, mutect2, varscan2
- CC2D1B | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs778402049, COSV52558603; called by muse, mutect2, varscan2
- CDC42BPA | c.4249G>T p.E1417* (on ENST00000334218 / NM_001366019.2; = p.E1404* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as COSV62002070; called by muse, mutect2, varscan2
- CDC42BPB | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV63473822; called by muse, mutect2, varscan2
- CEP170 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 100/231 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV60505947; called by muse, mutect2, varscan2
- CFAP157 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV58852012; called by muse, mutect2, varscan2
- CFAP251 | c.2888C>T p.S963F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV56607810; called by muse, mutect2, varscan2
- CFAP69 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV60184130; called by muse, mutect2
- CHN1 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV69294775; called by muse, mutect2, varscan2
- CLEC14A | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.928); catalogued as rs888925775, COSV60561648; called by muse, mutect2, varscan2
- CROT | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1400049512, COSV58972783; called by muse, mutect2, varscan2
- CTSS | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV64565838; called by muse, mutect2
- CYP3A7 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60480452; called by muse, mutect2, varscan2
- DAP | c.215dup p.A73Gfs*68 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs777516488; called by pindel, varscan2
- DCAF8L1 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV71595108; called by muse, mutect2, varscan2
- DCLRE1C | c.1993G>C p.E665Q (on ENST00000378278 / NM_001350965.2; = p.E550Q on NM_022487.4) | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV57952365; called by muse, mutect2, varscan2
- DDX4 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1236610959, COSV61753364; called by muse, mutect2, varscan2
- DENND1A | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.722); catalogued as COSV65322216; called by muse, mutect2, varscan2
- DHPS | c.108C>G p.F36L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV52951488; called by muse, mutect2, varscan2
- DIP2A | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs763963275, COSV59471670; called by muse, mutect2, varscan2
- DIP2B | c.3997G>A p.D1333N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56578672; called by muse, mutect2, varscan2
- DIS3L2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.224); catalogued as rs376340398; called by muse, mutect2
- DMXL2 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV51840627; called by muse, mutect2, varscan2
- DNAJC3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV65130430; called by muse, mutect2, varscan2
- EFHC2 | c.834C>A p.F278L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV69552720; called by muse, mutect2, varscan2
- ERCC6L | c.2928G>C p.E976D | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV57819338; called by muse, mutect2, varscan2
- F9 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.362); catalogued as CM045773, COSV54378624; called by muse, mutect2, varscan2
- FAM13A | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV51996456; called by muse, mutect2, varscan2
- FBN2 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs150735582, COSV52512855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXW2 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61596423; called by muse, mutect2, varscan2
- FERMT3 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1030764940, COSV54176773; called by muse, mutect2
- GCM2 | c.1197G>T p.M399I | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1471190383, COSV65275082, COSV65276634; called by muse, mutect2, varscan2
- GRIA3 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52049045, COSV52060711; called by muse, mutect2, varscan2
- GRIN2C | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV53109737; called by muse, mutect2, varscan2
- GTF2E2 | c.259-1G>A p.X87_splice | Splice Site (SNP) | VAF 32/112 reads (29%) | catalogued as COSV63478073; called by muse, mutect2, varscan2
- GYG1 | c.539G>T p.R180I | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV56048618, COSV56050345; called by muse, mutect2, varscan2
- H1-5 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV100138139, COSV58898985; called by muse, mutect2, varscan2
- H2BC7 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100587227, COSV61911476, COSV61912249; called by muse, mutect2, varscan2
- HNRNPL | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV55491050, COSV99669941; called by muse, mutect2, varscan2
- IARS1 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV65113908; called by muse, mutect2, varscan2
- IPO5 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs9584741, COSV55152051; called by muse, mutect2, varscan2
- KATNA1 | c.69C>G p.D23E | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV104427099, COSV59501309; called by muse, mutect2, varscan2
- KDF1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV57670800; called by muse, mutect2
- KMT2A | c.8606C>T p.S2869L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63281845, COSV63291565; called by muse, mutect2, varscan2
- KNTC1 | c.5186G>A p.R1729H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs766109359, COSV61078792; called by muse, mutect2, varscan2
- KRTAP6-1 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 80/697 reads (11%) | PolyPhen probably damaging (0.979); catalogued as COSV58167791; called by muse, mutect2, varscan2
- L2HGDH | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 46/703 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV55555854; called by muse, mutect2
- LMAN1L | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV59000560; called by muse, mutect2, varscan2
- LMO2 | c.241C>T p.R81W (on ENST00000395833 / NM_001142315.2; = p.R150W on NM_005574.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145191677; called by muse, mutect2, varscan2
- LONRF3 | c.1192G>C p.E398Q (on ENST00000371628 / NM_001031855.3; = p.E357Q on NM_024778.5) | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV59149650; called by muse, mutect2, varscan2
- LTB4R2 | c.1037G>A p.R346Q (on ENST00000528054; = p.R315Q on NM_019839.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs761046681, COSV51864506; called by muse, mutect2, varscan2
- LTBP1 | c.2086C>T p.H696Y (on ENST00000404816 / NM_206943.4; = p.H370Y on NM_000627.4) | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs932972370, COSV63179604; called by muse, mutect2, varscan2
- MALT1 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV61934034; called by muse, mutect2, varscan2
- MARK1 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65065456; called by muse, mutect2, varscan2
- MED17 | c.1046C>G p.S349* | Nonsense Mutation (SNP) | VAF 18/208 reads (9%) | catalogued as COSV52599283; called by muse, mutect2
- MFSD11 | c.683-1G>A p.X228_splice | Splice Site (SNP) | VAF 54/117 reads (46%) | catalogued as rs1399233017, COSV60620565, COSV60629535; called by muse, mutect2, varscan2
- MTA3 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs190465226, COSV63196847; called by muse, mutect2
- MUC16 | c.9627G>T p.M3209I | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV67444033; called by muse, mutect2
- MUC17 | c.9644C>G p.S3215* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | catalogued as COSV60279725; called by muse, mutect2, varscan2
- MYLK | c.637A>C p.N213H | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV60604552; called by muse, mutect2, varscan2
- MYO9A | c.6722A>T p.E2241V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV61847508; called by muse, mutect2, varscan2
- N4BP2 | c.4384C>G p.Q1462E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV54698880, COSV54706032; called by muse, mutect2, varscan2
- NDNF | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as rs770532994, COSV65632502; called by muse, mutect2, varscan2
- NEB | c.17364G>C p.K5788N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV50809088; called by muse, mutect2
- NEB | c.11239G>C p.D3747H | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50809145; called by muse, mutect2, varscan2
- NLRP7 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs368470657, COSV60170912; called by muse, mutect2
- NRCAM | c.2305C>A p.P769T (on ENST00000379028 / NM_001371124.1; = p.P753T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773133428, COSV61031004; called by muse, mutect2, varscan2
- OR10G4 | c.489C>A p.F163L | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100304893, COSV57979018; called by muse, mutect2
- OR4D11 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV57584565, COSV57587417; called by muse, mutect2, varscan2
- PABPC3 | c.42C>G p.Y14* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | catalogued as COSV55797176, COSV55798143; called by muse, mutect2
- PAG1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55055368; called by muse, mutect2, varscan2
- PCF11 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as COSV53527390, COSV53531847; called by muse, mutect2, varscan2
- PCF11 | c.3118G>C p.D1040H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV53527416; called by muse, mutect2
- PDCD11 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV58915249; called by muse, mutect2, varscan2
- PDCD6 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV53776009; called by muse, mutect2, varscan2
- PDHA1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV58825889; called by muse, mutect2, varscan2
- PELI1 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62729405; called by muse, mutect2, varscan2
- PLAGL2 | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as COSV55787336; called by muse, mutect2, varscan2
- PPP1R7 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV52143452; called by muse, varscan2
- PPP2R3A | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs369517042; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1087C>T p.Q363* (on ENST00000352766; = p.Q284* on NM_181334.5) | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV61231609; called by muse, mutect2, varscan2
- PTGFRN | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314187429, COSV67797677; called by muse, mutect2, varscan2
- PTH2R | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs149710383; called by muse, mutect2
- PTPN13 | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100365091; called by muse, mutect2
- QSER1 | c.2206C>G p.L736V (on ENST00000399302; = p.L865V on NM_001076786.3) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV67899488, COSV67900955; called by muse, mutect2, varscan2
- QSER1 | c.2372C>G p.S791C (on ENST00000399302; = p.S920C on NM_001076786.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV67899492; called by muse, mutect2, varscan2
- RBM25 | c.1651C>G p.L551V | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV56198466; called by muse, mutect2, varscan2
- RCBTB2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV60649048; called by muse, mutect2, varscan2
- RFFL | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.164); catalogued as COSV52070678; called by muse, mutect2, varscan2
- RIC1 | c.2884C>G p.L962V | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471122411, COSV52604855, COSV99317759; called by muse, mutect2, varscan2
- RIN2 | c.1117C>G p.R373G (on ENST00000255006 / NM_001242581.1; = p.R324G on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54784052, COSV99657639; called by muse, mutect2, varscan2
- ROPN1 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51739112; called by mutect2, varscan2
- RTL9 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV71825394; called by muse, mutect2, varscan2
- SCRN1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV54128255; called by muse, mutect2
- SETX | c.5566G>A p.E1856K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs757652780, COSV56378682, COSV99809931; called by muse, mutect2, varscan2
- SETX | c.3961G>A p.D1321N | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56378696; called by muse, mutect2, varscan2
- SGSM1 | c.2950C>G p.L984V (on ENST00000400359 / NM_001039948.4; = p.L923V on NM_133454.3) | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63082281, COSV63082415; called by muse, mutect2, varscan2
- SHANK1 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53242748, COSV53254769; called by muse, mutect2, varscan2
- SI | c.4801C>A p.H1601N | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV52265690, COSV52283499; called by muse, mutect2, varscan2
- SLC13A4 | c.1853G>C p.R618T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62459899; called by muse, mutect2, varscan2
- SLC22A8 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 23/360 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV100267967; called by muse, mutect2
- SLC38A1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV67062888, COSV67063367; called by muse, mutect2, varscan2
- SMC6 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | catalogued as COSV61171354; called by muse, varscan2
- SPEN | c.7369G>A p.D2457N | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.971); catalogued as COSV65357590; called by muse, mutect2, varscan2
- SPEN | c.7498G>C p.E2500Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV65357595; called by muse, mutect2, varscan2
- SPEN | c.7747G>A p.E2583K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as rs764911348, COSV65357600, COSV65360467; called by muse, mutect2, varscan2
- SPTA1 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV63748733, COSV63753091; called by muse, mutect2
- STARD13 | c.125G>C p.S42T | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as COSV60241894; called by muse, mutect2, varscan2
- STN1 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs146909879; called by muse, mutect2
- SUN1 | c.499C>G p.Q167E (on ENST00000405266 / NM_001367651.1; = p.Q117E on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV61777376; called by muse, mutect2, varscan2
- TMEM169 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 158/968 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs964253350, COSV55264128; called by muse, mutect2, varscan2
- TMEM47 | c.227-1G>A p.X76_splice | Splice Site (SNP) | VAF 45/305 reads (15%) | catalogued as COSV52063516; called by muse, mutect2, varscan2
- TRERF1 | c.3069G>A p.V1023= | Splice Region (SNP) | VAF 38/83 reads (46%) | catalogued as COSV61666836; called by muse, mutect2, varscan2
- TRMT2B | c.1148G>A p.R383K | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.04); catalogued as COSV58618427; called by muse, mutect2, varscan2
- TRPC5 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV53283771, COSV53303581; called by muse, mutect2, varscan2
- TRPS1 | c.3013G>A p.E1005K (on ENST00000220888 / NM_001330599.2; = p.E1018K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV55226191; called by muse, mutect2, varscan2
- TTN | c.82414G>A p.G27472R (on ENST00000591111; = p.G20048R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV59883074; called by muse, mutect2, varscan2
- UMODL1 | c.201del p.W67* | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as COSV68576109; called by mutect2, pindel*, varscan2
- WRN | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV53295943; called by muse, mutect2, varscan2
- ZAP70 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201606579, COSV53852473; called by muse, mutect2, varscan2
- ZDBF2 | c.6529C>G p.H2177D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV65621793; called by muse, mutect2, varscan2
- ZIC1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV51550542, COSV51557029; called by muse, mutect2, varscan2
- ZNF211 | c.461A>T p.Q154L (on ENST00000347302 / NM_198855.4; = p.Q167L on NM_006385.5) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV53739819; called by muse, mutect2, varscan2
- ZNF473 | c.2564C>G p.S855W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs957062054, COSV54521959; called by muse, mutect2, varscan2
- ZNF555 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV62072693, COSV62072745; called by muse, mutect2
- ZNF587 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 40/231 reads (17%) | catalogued as COSV57146636; called by muse, mutect2, varscan2
- ZNF625 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs748474291, COSV63241185; called by muse, mutect2, varscan2
- ZNF626 | c.660G>C p.K220N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV74128914, COSV74129159; called by muse, mutect2, varscan2
- ACTL7A | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.257); called by muse, mutect2
- FRG2C | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 67/489 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- STRN | c.2135del p.L712* | Frame Shift Del (DEL) | VAF 24/170 reads (14%) | called by mutect2, pindel, varscan2
- TRAV3 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TRBV19 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- A2M | c.2211G>A p.E737= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV59382479; called by muse, mutect2, varscan2
- ABCF3 | c.1959C>T p.L653= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs773550936, COSV53051336; called by muse, mutect2, varscan2
- ASB5 | c.273A>T p.S91= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV56668503; called by muse, mutect2, varscan2
- ATP1A3 | c.2817C>T p.I939= (on ENST00000545399 / NM_001256214.2; = p.I926= on NM_152296.5) | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as rs1555859155, COSV57484985; called by muse, mutect2, varscan2
- CAPN3 | c.2418C>T p.I806= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV55513559; called by muse, mutect2, varscan2
- CCR2 | c.762C>T p.L254= | Silent (SNP) | VAF 70/130 reads (54%) | catalogued as COSV52747582; called by muse, mutect2
- CD72 | c.120G>A p.E40= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV52410132; called by muse, mutect2, varscan2
- CD72 | c.30G>A p.L10= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV52410139; called by muse, mutect2, varscan2
- CDH11 | c.1167C>T p.I389= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV51751030; called by muse, mutect2, varscan2
- CHD5 | c.2298C>T p.R766= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs566097871, COSV52407293; called by muse, mutect2, varscan2
- CHRNB2 | c.687C>T p.I229= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as COSV63807672; called by muse, mutect2, varscan2
- CLIP3 | c.552G>A p.A184= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs759391047, COSV62111679; called by muse, mutect2, varscan2
- DAPK1 | c.120C>T p.A40= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs374777068, COSV63790360; called by muse, mutect2, varscan2
- DPY19L4 | c.1347G>A p.L449= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as COSV68962216; called by muse, mutect2, varscan2
- ELP3 | c.903C>T p.F301= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV56457665; called by muse, mutect2, varscan2
- ERCC4 | c.2187C>T p.I729= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs746273815, COSV61310602; called by muse, mutect2, varscan2
- FBXW11 | c.1518C>T p.I506= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV51605254; called by muse, mutect2, varscan2
- FEM1A | c.1350C>T p.A450= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs755591503, COSV54162952; called by muse, mutect2, varscan2
- FRMD4A | c.955C>T p.L319= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV52714349; called by muse, mutect2, varscan2
- GOLGA1 | c.864G>A p.E288= | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as COSV65220980, COSV65221127, COSV65221396; called by muse, mutect2, varscan2
- GPR39 | c.252C>T p.L84= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV61421036; called by muse, mutect2, varscan2
- GRIN2B | c.165G>A p.E55= | Silent (SNP) | VAF 61/156 reads (39%) | catalogued as COSV74204743; called by muse, varscan2
- H2BC17 | c.270C>T p.I90= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV58151949; called by muse, mutect2, varscan2
- HDLBP | c.2643C>T p.P881= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV60491957; called by muse, mutect2, varscan2
- HTT | c.3849G>T p.L1283= | Silent (SNP) | VAF 69/422 reads (16%) | catalogued as COSV61857262; called by muse, mutect2, varscan2
- HYDIN | c.6111C>T p.I2037= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs1362569437, COSV59249123; called by muse, mutect2, varscan2
- IGSF8 | c.681C>G p.A227= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV58757343; called by muse, mutect2, varscan2
- IQSEC2 | c.2745G>A p.L915= (on ENST00000642864 / NM_001111125.3; = p.L710= on NM_015075.2) | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV64723346; called by muse, mutect2, varscan2
- ITGB3BP | c.417C>T p.T139= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV52130193, COSV99371261; called by muse, mutect2, varscan2
- ITIH4 | c.912C>T p.L304= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1180884224, COSV56571247; called by muse, mutect2, varscan2
- KCNS2 | c.681C>T p.F227= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs1293029451, COSV54637160; called by muse, mutect2, varscan2
- KIF4A | c.2367G>A p.E789= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV63285029; called by muse, mutect2, varscan2
- KIF6 | c.2109C>T p.L703= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs763515741, COSV54666634; called by muse, mutect2, varscan2
- KRT76 | c.1296T>C p.A432= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV60119067; called by muse, mutect2, varscan2
- LAMC3 | c.738C>T p.D246= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs778312863, COSV100736068, COSV63088511; called by muse, mutect2, varscan2
- LINGO2 | c.255G>A p.E85= | Silent (SNP) | VAF 67/240 reads (28%) | catalogued as COSV100430741, COSV58056887; called by muse, mutect2, varscan2
- MBTPS2 | c.48C>T p.V16= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV63410676; called by muse, mutect2, varscan2
- MPP6 | c.582G>A p.L194= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV56035254; called by muse, mutect2, varscan2
- MTFR2 | c.663C>G p.L221= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as COSV63078576, COSV63079009; called by muse, mutect2, varscan2
- MTHFD2 | c.16C>T p.L6= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV51201005; called by muse, mutect2, varscan2
- NCOA6 | c.3312C>T p.P1104= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs760258328, COSV62861266; called by muse, mutect2, varscan2
- NOD2 | c.1158C>T p.F386= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV56048269; called by mutect2, varscan2
- OCRL | c.84C>T p.C28= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV63980069; called by muse, mutect2, varscan2
- PLA2G6 | c.1098C>T p.I366= | Silent (SNP) | VAF 12/191 reads (6%) | catalogued as COSV59267896; called by muse, mutect2
- POLR3K | c.69C>T p.F23= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1209565587, COSV51953465, COSV51956181; called by muse, mutect2, varscan2
- PRKDC | c.2280G>A p.L760= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV58042406; called by muse, mutect2, varscan2
- PROM2 | c.2133G>A p.L711= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV58296572; called by muse, mutect2, varscan2
- PTK6 | c.742C>T p.L248= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53915838; called by muse, mutect2, varscan2
- RYR3 | c.9933G>A p.E3311= (on ENST00000389232; = p.E3312= on NM_001036.6) | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs754872142, COSV66777354; called by muse, mutect2, varscan2
- SALL4 | c.2547G>A p.S849= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs780919557, COSV53849736; called by muse, mutect2, varscan2
- SFTPB | c.561G>A p.A187= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs543913426, COSV60892598; called by muse, mutect2, varscan2
- SMC2 | c.576G>A p.L192= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV53954943; called by muse, mutect2, varscan2
- SNX24 | c.360A>G p.T120= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as COSV54446620; called by muse, mutect2, varscan2
- SPEN | c.8079G>C p.L2693= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV65357606; called by muse, mutect2, varscan2
- SPEN | c.9585G>A p.V3195= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV65357625; called by muse, mutect2, varscan2
- SPON2 | c.882G>A p.G294= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs565096289, COSV52054150; called by muse, mutect2
- SYNE1 | c.17466G>A p.E5822= (on ENST00000367255 / NM_182961.4; = p.E5751= on NM_033071.3) | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs368601212, COSV54904389; called by muse, mutect2, varscan2
- TDRD3 | c.267G>A p.P89= | Silent (SNP) | VAF 53/513 reads (10%) | catalogued as rs770819975, COSV52153030, COSV52156894; called by muse, mutect2, varscan2
- TNK1 | c.189G>A p.L63= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1390520217, COSV61169886, COSV61172238; called by muse, mutect2, varscan2
- VCPKMT | c.689G>A p.*230= | Silent (SNP) | VAF 9/283 reads (3%) | catalogued as COSV67775988; called by muse, mutect2
- ZFHX4 | c.6309C>T p.D2103= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs781387338, COSV50490459; called by muse, mutect2, varscan2
- ZNF382 | c.765C>T p.L255= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV53085899, COSV99497535; called by muse, mutect2, varscan2
- ZNF92 | c.166C>T p.L56= | Silent (SNP) | VAF 86/270 reads (32%) | catalogued as COSV60873003; called by muse, mutect2, varscan2
- AFDN | chr6:167825958 T>C | 5'Flank (SNP) | VAF 8/64 reads (13%) | catalogued as rs763454767; called by muse, mutect2, varscan2
- AFDN | chr6:167826035 A>T | 5'Flank (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- IL36B | c.261+898C>A | Intron (SNP) | VAF 59/348 reads (17%) | catalogued as COSV52084448; called by muse, mutect2, varscan2
- ING1 | chr13:110714218 C>G | 5'Flank (SNP) | VAF 3/15 reads (20%) | catalogued as COSV58166583, COSV58167251; called by muse, mutect2
- LGALS14 | c.16-594G>T | Intron (SNP) | VAF 57/249 reads (23%) | catalogued as COSV62372149; called by muse, mutect2, varscan2
- MIR124-1 | n.33G>C | RNA (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- RIPOR3 | chr20:50585858 del CTGCTGATG | 3'Flank (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
